Somatic mutation profile of tumor specimen MMRF_2438_1_BM_CD138pos (aliquot MMRF_2438_1_BM_CD138pos_T1_KHS5U_K15197) from MMRF case MMRF_2438, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.6 years (18,846 days).
Specimen MMRF_2438_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 557efeb2-0b7a-4a2f-8499-d4ec98ed5d68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2438_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2438_1_PB_Whole_C3_KHS5U_K15198; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abc00d19-64fc-4a33-80f1-4d785360a213

The open-access MAF lists 271 somatic variants for this specimen: 100 protein-altering or splice-affecting, 42 silent, 129 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, 3'UTR 58, Silent 42, Intron 33, 5'UTR 13, 5'Flank 10, RNA 8, 3'Flank 7, Nonsense Mutation 5, Frame Shift Del 3, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFP | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV56925609; called by muse, mutect2
- ARFGAP2 | c.1417C>T p.H473Y | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV53565510; called by muse, mutect2, varscan2
- B4GALNT1 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771628032, COSV57543089; called by muse, mutect2, varscan2
- C2 | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 7/210 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs755835929; called by muse, mutect2
- CSMD3 | c.6208G>T p.V2070F (on ENST00000297405 / NM_001363185.1; = p.V1966F on NM_052900.3) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99835849; called by muse, mutect2, varscan2
- CSMD3 | c.6207G>T p.M2069I (on ENST00000297405 / NM_001363185.1; = p.M1965I on NM_052900.3) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs1188901665; called by muse, mutect2, varscan2
- CYP1A2 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs145266863; called by muse, mutect2, varscan2
- EFHC2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775518457, COSV69553438; called by muse, mutect2, varscan2
- GALR1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs942125973; called by muse, mutect2
- IGHD6-25 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 75/81 reads (93%) | catalogued as rs577590165; called by muse, varscan2
- IGHV3-30 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 126/339 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.662); catalogued as rs761431810; called by muse, varscan2
- IGLL5 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs188930549, COSV73251050, COSV73251263; called by muse, mutect2, varscan2
- KCNB2 | c.1689G>T p.K563N | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs779733202; called by muse, mutect2
- KLHL6 | c.219T>A p.D73E | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201783932, COSV58064231, COSV58069724; called by muse, mutect2, varscan2
- LAMC1 | c.211A>T p.T71S | Missense Mutation (SNP) | VAF 114/334 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756565770; called by muse, mutect2, varscan2
- MEFV | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV54823446; called by muse, mutect2
- MFN1 | c.1279T>C p.F427L | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs1418311571; called by muse, mutect2, varscan2
- OR51M1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 123/333 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1455584006; called by muse, mutect2, varscan2
- PKD1 | c.3710C>T p.T1237M | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs376846132; called by muse, mutect2, varscan2
- PKDCC | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs374454176; called by muse, mutect2, varscan2
- PLCD3 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs746901268; called by muse, mutect2, varscan2
- POLR3A | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100965535; called by muse, mutect2
- PROM2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs758232721, COSV100468612; called by muse, mutect2
- PTPRM | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 100/330 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV100154721; called by muse, mutect2, varscan2
- PUM1 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 9/142 reads (6%) | catalogued as COSV99928086; called by muse, mutect2
- RFX3 | c.2099G>A p.S700N | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs931224520; called by muse, mutect2
- ROR2 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV65218467; called by muse, mutect2
- RPGR | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.508); catalogued as rs1409862085; called by muse, mutect2
- SCN1A | c.5182G>A p.G1728R (on ENST00000303395 / NM_001202435.3; = p.G1717R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100322250; called by muse, mutect2
- SFXN2 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141735494; called by muse, mutect2, varscan2
- SIGLEC12 | c.1030G>A p.V344M (on ENST00000291707 / NM_053003.4; = p.V226M on NM_033329.2) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375646481; called by muse, mutect2
- SLCO4C1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1413596660, COSV60514463; called by muse, mutect2
- SOWAHA | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1479784711; called by muse, mutect2
- TIAM1 | c.3152C>T p.T1051M | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54536943; called by muse, mutect2
- TMC3 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 118/225 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs143697026; called by muse, mutect2, varscan2
- TMX2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.416); catalogued as COSV53555145; called by muse, mutect2
- ZNF486 | c.303A>T p.K101N | Missense Mutation (SNP) | VAF 13/378 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs559002129, COSV100631256; called by muse, mutect2
- ZSCAN5B | c.29G>C p.G10A | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs1384913136; called by muse, mutect2
- ACTA1 | c.236C>G p.T79S | Missense Mutation (SNP) | VAF 5/124 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.052); called by muse, mutect2
- AFF3 | c.3175C>A p.Q1059K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.646); called by muse, mutect2
- ATOH1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BTBD18 | c.2059A>T p.R687W | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.161); called by muse, mutect2
- CCDC102A | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); called by muse, mutect2
- CERS6 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2
- CLDN18 | c.524T>G p.L175R | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COPS3 | c.246G>T p.Q82H | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2
- CREB3 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DAPK1 | c.1786C>T p.L596F | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- DIS3 | c.1484T>C p.L495P | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH11 | c.3607T>A p.Y1203N | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAI1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAJC25 | c.668A>C p.K223T | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- DUS3L | c.1769T>C p.L590P | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- EGR3 | c.1158del p.C386Wfs*22 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- ENO3 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FBN1 | c.2717C>A p.T906K | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.059); called by muse, mutect2
- FBXL2 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABBR1 | c.2320T>A p.Y774N | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- GPATCH8 | c.2743G>C p.D915H | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GRM7 | c.1626T>A p.C542* | Nonsense Mutation (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- GTF2IRD1 | c.1085G>T p.R362I | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAO1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HIPK1 | c.3088G>C p.G1030R | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- IGKV1-27 | c.276T>A p.D92E | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.067); called by muse, varscan2
- IGKV1D-42 | c.247A>T p.R83W | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- KIAA2012 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KLC3 | c.1513T>A p.*505Kext*47 | Nonstop Mutation (SNP) | VAF 9/175 reads (5%) | called by muse, mutect2
- KLHL1 | c.1180C>A p.L394M | Missense Mutation (SNP) | VAF 75/86 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LMAN1 | c.1352A>G p.D451G | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- LMTK3 | c.3698T>G p.L1233R | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- LPAR1 | c.836_837del p.L279Pfs*14 | Frame Shift Del (DEL) | VAF 44/169 reads (26%) | called by mutect2, pindel, varscan2
- LRP2BP | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 38/39 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- LRRC52 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.034); called by muse, mutect2
- LRRIQ3 | c.1318G>T p.V440L | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- LRRIQ3 | c.730A>C p.K244Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYST | c.887T>G p.F296C | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- MED16 | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 5/114 reads (4%) | called by muse, mutect2
- MROH2A | c.677A>G p.E226G | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUGGC | c.1154G>A p.R385K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR56B4 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- PPP1R9A | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- PSMD8 | c.785T>C p.I262T | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- PTCH1 | c.1558C>T p.H520Y | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PTF1A | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPL39 | c.103A>T p.I35F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- SCN7A | c.1996C>A p.L666I | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2
- SCNN1A | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- SREK1 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SRP68 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SULT1C2 | c.314T>C p.I105T | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2
- SYT16 | c.500A>T p.E167V | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2
- TAS2R38 | c.975C>G p.H325Q | Missense Mutation (SNP) | VAF 27/793 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- THAP12 | c.509T>C p.F170S | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- UBQLN2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- UNC79 | c.896C>T p.T299I (on ENST00000393151 / NM_001346218.2; = p.T122I on NM_020818.5) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- YLPM1 | c.3538del p.M1180Cfs*27 | Frame Shift Del (DEL) | VAF 21/185 reads (11%) | called by mutect2, pindel, varscan2
- ZBED9 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
- ZDHHC5 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZMAT2 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.02); called by muse, mutect2
- ZMPSTE24 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- ADAMTS6 | c.3336G>A p.K1112= | Silent (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- C2CD5 | c.363A>G p.E121= | Silent (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- C2orf16 | c.4131C>T p.D1377= | Silent (SNP) | VAF 82/174 reads (47%) | catalogued as rs373912991, COSV100820641; called by muse, mutect2, varscan2
- C3 | c.1077G>A p.K359= | Silent (SNP) | VAF 86/348 reads (25%) | called by muse, mutect2, varscan2
- CDC42BPG | c.1047G>A p.T349= | Silent (SNP) | VAF 69/144 reads (48%) | catalogued as rs749844783; called by muse, mutect2, varscan2
- CEMIP2 | c.1914C>A p.S638= | Silent (SNP) | VAF 47/147 reads (32%) | catalogued as rs759380773; called by muse, mutect2, varscan2
- CHD8 | c.7239G>A p.E2413= (on ENST00000646647 / NM_001170629.2; = p.E2134= on NM_020920.4) | Silent (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- CORIN | c.705G>A p.P235= | Silent (SNP) | VAF 53/91 reads (58%) | catalogued as rs755107174, COSV56690711; called by muse, mutect2, varscan2
- CUEDC1 | c.291C>T p.G97= | Silent (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- CYP4F2 | c.1530C>T p.G510= | Silent (SNP) | VAF 39/149 reads (26%) | catalogued as rs1486329751, COSV99686421; called by muse, mutect2, varscan2
- DCAF8 | c.504C>A p.R168= | Silent (SNP) | VAF 9/194 reads (5%) | called by muse, mutect2
- EGR1 | c.93C>T p.N31= | Silent (SNP) | VAF 177/274 reads (65%) | called by muse, mutect2, varscan2
- EHD2 | c.507C>T p.Y169= | Silent (SNP) | VAF 189/313 reads (60%) | catalogued as rs200207567; called by muse, mutect2, varscan2
- ELMO3 | c.1635G>A p.K545= (on ENST00000652269; = p.K492= on NM_024712.5) | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- EML1 | c.2160C>A p.T720= | Silent (SNP) | VAF 90/178 reads (51%) | called by muse, mutect2, varscan2
- EPB41L2 | c.981C>T p.P327= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs779244974; called by muse, mutect2, varscan2
- FER1L5 | c.1230C>T p.L410= | Silent (SNP) | VAF 92/224 reads (41%) | catalogued as rs749401774; called by muse, mutect2, varscan2
- FGF9 | c.486C>T p.Y162= | Silent (SNP) | VAF 26/175 reads (15%) | called by muse, mutect2, varscan2
- FUT5 | c.846C>T p.A282= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs764440838; called by muse, mutect2, varscan2
- HCN1 | c.2538G>A p.S846= | Silent (SNP) | VAF 7/198 reads (4%) | called by muse, mutect2
- HEPACAM | c.543G>A p.L181= | Silent (SNP) | VAF 61/134 reads (46%) | called by muse, mutect2, varscan2
- IGKV1-27 | c.186A>T p.P62= | Silent (SNP) | VAF 75/271 reads (28%) | catalogued as rs768985059; called by muse, mutect2, varscan2
- IRS4 | c.2289T>C p.D763= | Silent (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- LAS1L | c.726C>T p.A242= | Silent (SNP) | VAF 63/80 reads (79%) | catalogued as rs35447939; called by muse, mutect2, varscan2
- LOXHD1 | c.4677A>C p.L1559= | Silent (SNP) | VAF 21/284 reads (7%) | called by muse, mutect2
- MIA3 | c.4329G>A p.R1443= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV100485064; called by muse, mutect2
- NUP153 | c.693C>T p.F231= | Silent (SNP) | VAF 70/204 reads (34%) | called by muse, mutect2, varscan2
- OR2T3 | c.366C>G p.A122= | Silent (SNP) | VAF 124/430 reads (29%) | called by muse, mutect2
- ORC4 | c.192T>C p.L64= | Silent (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- PASK | c.3324C>T p.I1108= | Silent (SNP) | VAF 5/127 reads (4%) | catalogued as COSV52154528; called by muse, mutect2
- PCED1A | c.639G>T p.G213= | Silent (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- PGK2 | c.672C>T p.I224= | Silent (SNP) | VAF 39/175 reads (22%) | catalogued as rs776539984, COSV100505330; called by muse, mutect2, varscan2
- PLB1 | c.2073C>T p.I691= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as rs774350142; called by muse, mutect2, varscan2
- PLXNA1 | c.4860C>T p.L1620= | Silent (SNP) | VAF 88/315 reads (28%) | catalogued as rs769218566, COSV99304156; called by muse, mutect2, varscan2
- PODXL2 | c.735G>C p.L245= | Silent (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- PTPN21 | c.1914C>T p.I638= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs1478633008, COSV100162578; called by muse, mutect2, varscan2
- SH3BP4 | c.219A>T p.T73= | Silent (SNP) | VAF 34/135 reads (25%) | called by muse, mutect2, varscan2
- SPTBN1 | c.1330C>T p.L444= | Silent (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- STOX2 | c.897C>T p.D299= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as rs377137784; called by muse, mutect2, varscan2
- TPCN2 | c.1791G>A p.G597= | Silent (SNP) | VAF 8/246 reads (3%) | catalogued as rs1482752350; called by muse, mutect2
- TTN | c.30222G>A p.R10074= (on ENST00000591111; = p.R9147= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- UFD1 | c.810C>T p.F270= | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- ABI2 | c.*1465C>G | 3'UTR (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- AGPS | chr2:177392675 A>G | 5'Flank (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- AHR | c.-467C>T | 5'UTR (SNP) | VAF 21/126 reads (17%) | called by muse, mutect2, varscan2
- ALDH7A1 | c.774-13T>G | Intron (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2
- ALDH8A1 | c.*799G>A | 3'UTR (SNP) | VAF 76/112 reads (68%) | called by muse, mutect2, varscan2
- ALPK2 | c.*380_*428del | 3'UTR (DEL) | VAF 14/93 reads (15%) | called by mutect2, pindel
- ALPK2 | c.*280T>G | 3'UTR (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- APBB3 | c.627-58G>A | Intron (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- AQP6 | c.403-320G>A | Intron (SNP) | VAF 69/262 reads (26%) | catalogued as rs981487340; called by muse, mutect2, varscan2
- ASCC3 | c.*581G>A | 3'UTR (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- ASIC2 | c.556-180375A>G | Intron (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- ATM | c.-9T>C | 5'UTR (SNP) | VAF 22/258 reads (9%) | called by muse, mutect2
- BCAS1 | chr20:53940028 G>A | 3'Flank (SNP) | VAF 45/91 reads (49%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021366 C>G | 5'Flank (SNP) | VAF 59/128 reads (46%) | catalogued as COSV104379300; called by muse, mutect2, varscan2
- BPTF | chr17:67825506 C>T | 5'Flank (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- C21orf58 | c.-876C>A | 5'UTR (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- CACNA1D | c.1220+615C>T | Intron (SNP) | VAF 6/133 reads (5%) | called by muse, mutect2
- CARS2 | c.1417-228C>T | Intron (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- CASS4 | chr20:56458867 G>A | 3'Flank (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- CD47 | c.*656C>T | 3'UTR (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- CFAP44 | c.*4552C>T | 3'UTR (SNP) | VAF 18/289 reads (6%) | called by muse, mutect2
- CFAP46 | c.7584-196G>A | Intron (SNP) | VAF 50/69 reads (72%) | catalogued as rs759198502; called by muse, mutect2
- CHD8 | c.844-124G>C | Intron (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- CHIC2 | c.*55T>A | 3'UTR (SNP) | VAF 32/528 reads (6%) | called by muse, mutect2
- CHMP6 | c.-51C>T | 5'UTR (SNP) | VAF 14/35 reads (40%) | catalogued as rs777642121; called by muse, mutect2, varscan2
- COG3 | c.*1260G>A | 3'UTR (SNP) | VAF 6/59 reads (10%) | catalogued as rs985825010, COSV104415059; called by muse, mutect2, varscan2
- COX7B | chrX:77899460 G>C | 5'Flank (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- CPAMD8 | c.5568-1034C>A | Intron (SNP) | VAF 11/246 reads (4%) | catalogued as rs1442891467; called by muse, mutect2
- CSNK1G1 | c.*1909T>C | 3'UTR (SNP) | VAF 15/193 reads (8%) | catalogued as rs567919044; called by muse, mutect2
- CTSL | c.127-98C>T | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- CUL9 | c.4159+43C>A | Intron (SNP) | VAF 31/205 reads (15%) | called by muse, mutect2, varscan2
- DAB1 | c.-11G>A | 5'UTR (SNP) | VAF 20/253 reads (8%) | catalogued as COSV100139149; called by muse, mutect2
- DHRS12 | chr13:51804239 C>A | 5'Flank (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- DIPK1B | chr9:136726862 A>T | 3'Flank (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- DOCK4 | c.*375G>A | 3'UTR (SNP) | VAF 62/134 reads (46%) | called by muse, mutect2, varscan2
- DOP1B | c.-30C>T | 5'UTR (SNP) | VAF 73/94 reads (78%) | catalogued as rs917870346; called by muse, mutect2, varscan2
- DTX1 | c.-376G>T | 5'UTR (SNP) | VAF 32/52 reads (62%) | called by muse, mutect2
- DYDC1 | c.-9-72T>G | Intron (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- EIF4A2 | chr3:186783257 C>T | 5'Flank (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2
- ELMO1 | c.1437+27194G>A | Intron (SNP) | VAF 18/57 reads (32%) | catalogued as rs756352329; called by muse, mutect2
- EMD | c.266-52C>G | Intron (SNP) | VAF 44/59 reads (75%) | called by muse, mutect2, varscan2
- ERGIC3 | chr20:35559205 G>A | 3'Flank (SNP) | VAF 15/171 reads (9%) | catalogued as rs765459203; called by muse, mutect2
- ESRP2 | c.*530T>C | 3'UTR (SNP) | VAF 52/95 reads (55%) | called by muse, mutect2, varscan2
- ETDA | chrX:135248972 T>G | 5'Flank (SNP) | VAF 12/50 reads (24%) | called by mutect2, varscan2
- ETV1 | c.*889C>T | 3'UTR (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- EYS | c.1767-8025C>A | Intron (SNP) | VAF 20/56 reads (36%) | called by mutect2, varscan2
- FAM53C | c.*1505G>A | 3'UTR (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- FST | c.*934T>C | 3'UTR (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- GXYLT1 | c.*4046A>G | 3'UTR (SNP) | VAF 25/105 reads (24%) | catalogued as rs936944249; called by muse, mutect2, varscan2
- HBS1L | c.*858C>T | 3'UTR (SNP) | VAF 9/123 reads (7%) | called by muse, mutect2
- IGKV2-29 | n.164A>C | RNA (SNP) | VAF 64/149 reads (43%) | called by muse, mutect2, varscan2
- IGSF10 | c.*3024T>A | 3'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- IL17RD | c.*808T>C | 3'UTR (SNP) | VAF 13/209 reads (6%) | called by muse, mutect2
- ITGA10 | c.*719C>T | 3'UTR (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- KCNJ12 | c.*438A>C | 3'UTR (SNP) | VAF 10/37 reads (27%) | catalogued as rs78347298; called by mutect2, varscan2
- KIAA1841 | c.*391T>G | 3'UTR (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- KIF1B | c.*3752C>T | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- KIF21B | c.1213-113G>A | Intron (SNP) | VAF 30/42 reads (71%) | catalogued as rs927384659; called by muse, mutect2
- LINC00173 | n.900C>T | RNA (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- LINC02145 | n.358C>T | RNA (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- MAFF | c.*1041A>C | 3'UTR (SNP) | VAF 22/92 reads (24%) | called by muse, varscan2
- MAP1LC3B | chr16:87391729 A>G | 5'Flank (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- MIR363 | chrX:134169908 A>G | 5'Flank (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- MIR520D | n.23G>T | RNA (SNP) | VAF 39/142 reads (27%) | called by muse, mutect2, varscan2
- MMP8 | c.*502C>A | 3'UTR (SNP) | VAF 51/106 reads (48%) | catalogued as rs917240520; called by muse, mutect2, varscan2
- MTA2 | c.372+45C>T | Intron (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- MYB | c.*889C>T | 3'UTR (SNP) | VAF 14/68 reads (21%) | catalogued as rs972763290, COSV57198452; called by muse, mutect2, varscan2
- NDUFB6 | c.-73G>A | 5'UTR (SNP) | VAF 22/286 reads (8%) | catalogued as rs141060013; called by muse, mutect2
- NOC2LP2 | n.1282C>A | RNA (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- NOM1 | c.*2734_*2738del | 3'UTR (DEL) | VAF 12/34 reads (35%) | catalogued as rs1414594765; called by mutect2, pindel, varscan2
- NRP2 | c.2440+9630C>A | Intron (SNP) | VAF 19/216 reads (9%) | called by muse, mutect2
- NRXN1 | c.832+1928A>G | Intron (SNP) | VAF 45/357 reads (13%) | called by muse, mutect2, varscan2
- OR10G1P | n.588A>G | RNA (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- OR5M4P | n.873T>C | RNA (SNP) | VAF 50/92 reads (54%) | called by muse, mutect2, varscan2
- OTOG | c.*704C>T | 3'UTR (SNP) | VAF 50/125 reads (40%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.6-100G>C | Intron (SNP) | VAF 50/184 reads (27%) | called by muse, mutect2, varscan2
- PBX1 | c.191+19T>G | Intron (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- PCDH11X | c.*2652G>A | 3'UTR (SNP) | VAF 178/261 reads (68%) | catalogued as rs367643365, COSV53459735; called by muse, varscan2
- PCDH19 | c.*2671G>A | 3'UTR (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- PCDH19 | c.*316T>G | 3'UTR (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- PEX5 | c.-31G>T | 5'UTR (SNP) | VAF 6/66 reads (9%) | catalogued as rs1034679625; called by muse, mutect2
- PHC3 | c.-36T>G | 5'UTR (SNP) | VAF 23/461 reads (5%) | called by muse, mutect2
- PKNOX2 | c.-130+23889G>A | Intron (SNP) | VAF 89/211 reads (42%) | catalogued as rs749906300, COSV53551132; called by muse, mutect2, varscan2
- PMP2 | c.*2989G>A | 3'UTR (SNP) | VAF 13/50 reads (26%) | catalogued as rs758740603; called by muse, mutect2, varscan2
- PPARGC1A | c.234+1586C>T | Intron (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- PPM1A | c.952+992G>A | Intron (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- PPM1L | c.-13C>T | 5'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- PPP3CA | c.*848T>G | 3'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- PRELP | c.*2137del | 3'UTR (DEL) | VAF 12/130 reads (9%) | called by mutect2, pindel
- PRSS40A | n.318-721G>A | Intron (SNP) | VAF 11/50 reads (22%) | called by mutect2, varscan2
- PSMB5 | c.*233A>G | 3'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as rs769957353; called by muse, varscan2
- PSMC3IP | c.34+31G>A | Intron (SNP) | VAF 8/84 reads (10%) | catalogued as rs903558630; called by muse, mutect2
- PXDN | c.2104+317A>T | Intron (SNP) | VAF 86/172 reads (50%) | called by muse, mutect2, varscan2
- RAG1 | c.*2237C>T | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- RBM7 | c.*1360C>T | 3'UTR (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- RFX4 | c.670-3127C>G | Intron (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- RGS16 | c.*919C>G | 3'UTR (SNP) | VAF 19/226 reads (8%) | called by muse, mutect2
- RTN4IP1 | c.-303T>C | 5'UTR (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- RTN4IP1 | c.-304T>G | 5'UTR (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- SCLY | c.946-107A>G | Intron (SNP) | VAF 46/91 reads (51%) | catalogued as rs1021983596; called by muse, mutect2, varscan2
- SEMA5A | c.*1103T>C | 3'UTR (SNP) | VAF 29/97 reads (30%) | catalogued as rs1336906975; called by muse, mutect2, varscan2
- SEMA6A | c.1730-381C>T | Intron (SNP) | VAF 9/150 reads (6%) | called by muse, mutect2
- SIM1 | chr6:100386980 C>T | 3'Flank (SNP) | VAF 4/75 reads (5%) | called by muse, mutect2
- SLC25A13 | c.1751-21G>A | Intron (SNP) | VAF 47/177 reads (27%) | called by muse, mutect2, varscan2
- SLC28A3 | c.*1126A>T | 3'UTR (SNP) | VAF 51/160 reads (32%) | called by muse, mutect2, varscan2
- SLC30A8 | c.*983G>A | 3'UTR (SNP) | VAF 6/101 reads (6%) | called by muse, mutect2
- SLITRK3 | c.*890C>G | 3'UTR (SNP) | VAF 34/103 reads (33%) | catalogued as COSV53847105; called by muse, mutect2, varscan2
- SRRM1 | c.*280G>A | 3'UTR (SNP) | VAF 81/175 reads (46%) | catalogued as rs868429598; called by muse, mutect2, varscan2
- ST6GAL1 | c.*1272T>G | 3'UTR (SNP) | VAF 40/139 reads (29%) | called by muse, mutect2, varscan2
- SVIP | c.*664G>A | 3'UTR (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- TIA1 | c.311-564G>A | Intron (SNP) | VAF 5/118 reads (4%) | called by muse, mutect2
- TIMM44 | c.*51C>A | 3'UTR (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- TMEM167A | c.*3239G>A | 3'UTR (SNP) | VAF 126/367 reads (34%) | called by muse, mutect2, varscan2
- TMEM250 | c.*27C>T | 3'UTR (SNP) | VAF 23/83 reads (28%) | catalogued as rs569324479; called by muse, mutect2, varscan2
- TPM4 | chr19:16076116 G>A | 5'Flank (SNP) | VAF 38/135 reads (28%) | catalogued as rs762496473; called by muse, mutect2, varscan2
- TRAF6P1 | n.1195C>T | RNA (SNP) | VAF 5/64 reads (8%) | catalogued as rs984801213; called by muse, mutect2
- TRIM59 | chr3:160435428 G>A | 3'Flank (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- TSPYL6 | c.*1070C>G | 3'UTR (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- TVP23B | c.*138G>T | 3'UTR (SNP) | VAF 26/352 reads (7%) | called by muse, mutect2
- TXNL1 | c.*5553C>T | 3'UTR (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- UTP25 | c.*683C>T | 3'UTR (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- VGLL3 | c.*7368T>C | 3'UTR (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- ZGLP1 | c.*44A>C | 3'UTR (SNP) | VAF 5/118 reads (4%) | called by muse, mutect2
- ZNF331 | c.*1295A>T | 3'UTR (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- ZNF425 | c.*705A>G | 3'UTR (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- ZNF568 | c.*637G>A | 3'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- ZNF711 | chrX:85272009 C>A | 3'Flank (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- ZNF813 | c.*423C>A | 3'UTR (SNP) | VAF 66/236 reads (28%) | called by muse, mutect2, varscan2
- ZSCAN25 | c.387+28C>T | Intron (SNP) | VAF 9/94 reads (10%) | catalogued as rs185059551, COSV53553070; called by muse, mutect2, varscan2
